Surgical pathology report (de-identified scan), TCGA case TCGA-LD-A74U, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Hartford Hospital, specimen TCGA-LD-A74U-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

1. RIGHT BREAST, PARTIAL MASTECTOMY: INVASIVE LOBULAR CARCINOMA

SIZE (INVASIVE): Approximately 70 mm; see comment
LATERALITY: Right
TUMOR FOCALITY: Unifocal
LESIONAL SITE: 9:00 (according to operative report)
HISTOLOGIC TYPE: Invasive lobular carcinoma, classical type, focal pleomorphic type
NUCLEAR GRADE: I of III (classical type) and II-III of III (pleomorphic type)
HISTOLOGIC GRADE: N/A (invasive lobular carcinoma)
IN-SITU COMPONENT: Not present
LYMPH NODE SAMPLING: Positive (11/12), (largest 45mm; with extranodal involvement); see specimen #2
AJCC CATEGORIES: Stage IIIC (assuming cM0" status)
pTNM: pT3 pN3a
cTNM: cT2 cN1 cM0
INTEGRITY/ORIENTATION: Intact specimen with designated margins
MARGINS (Invasive lobular): Negative
<0.1mm superior margin (1P, highlighted by CK7 immunostain); 0.2mm medial margin (1EE) and 1mm posterior margin (1N); other margins >3mm
LYMPHOVASCULAR INVASION: Focal suspicious for LVI
MICROCALCIFICATIONS: Not identified
NIPPLE/SKIN: (if applicable) Negative skin
SKELETAL MUSCLE: Not present
OTHER: Focal atypical lobular hyperplasia, sclerosing adenosis, usual ductal hyperplasia, apocrine metaplasia and prior biopsy site changes

ICD-O-3
Carcinoma, infiltrating lobular
mixed w/ other types
(pleomorphic) 8524/3
Date 8/22/13
Breast NOS C50.9
path B Breast, midline
C50.8
8/22/13

2. RIGHT AXILLARY NODE CONTENTS, DISSECTION: ELEVEN OUT OF TWELVE LYMPH NODES TOTALLY REPLACED BY METASTATIC LOBULAR CARCINOMA (11/12), LARGEST TUMOR 4.5 CM, EXTRANODAL EXTENSION PRESENT; ADDITIONAL INVASIVE LOBULAR CARCINOMA WITHIN THE FAT (ABOUT 2CM).

3. OMENTUM, RESECTION: ADIPOSE TISSUE; NEGATIVE FOR TUMOR.

Electronically Signed Out

COMMENT

Tumor grossly is 5.3 cm. In the axillary contents (#2), sizeable tumor mass within the fat is also present in multiple blocks, which most likely represents a direct extension from the lumpectomy, and thus the tumor size is estimated to be 7cm.
88307x2, 88305, 88329, 88342

Clinical Diagnosis and History:

Right breast cancer, gastric cancer

[page 2 of 3]
cT2,cN1,cM0 clinical stage II

Tissue(s) Submitted:

- 1: RIGHT BREAST MASS SHORT SUTURE SUPERIOR LONG SUTURE LATERAL
- 2: RIGHT AXILLARY NODE CONTENTS
- 3: OMENTUM

Gross Description:

Specimen #1 is received fresh for intraoperative consultation, labeled with the patient's name and right breast mass, and consists of an 11.3 cm (medial to lateral) x 8.5 cm (superior to inferior) x 4.5 cm (anterior to posterior) product of partial mastectomy which is surfaced by a 6.9 x 2.2 x 0.2 cm ellipse of unremarkable white tan skin. No nipple is identified. A short suture designating superior and a long suture designating lateral are present. Two needle localization wires are entering the specimen in the superior and inferior aspects. The specimen is radiographed and differentially inked as follows: superior-blue, inferior-green, lateral-yellow, medial-red, posterior/deep-black and serially sectioned from lateral to medial into 10 slices. No biopsy clip is identified. An ill-defined, rubbery to firm, white-tan area measuring 5.3 x 5.0 x 3.5 cm is identified in slices 4 to 10. This area of fibrous tissue shows some extensions to the posterior, inferior, superior, and medial margins. This fibrous area is also 2.0 cm from the overlying skin. No other lesions are grossly identified. The breast parenchyma consists of tan-yellow, lobulated adipose tissue (60%) and fibrous tissue (40%). Time in formalin: Some tumor and normal tissue is frozen for TCGA studies.

Representative sections of all slices (with the exception of slices 2 and 3) are submitted as follows:

- 1A-1B: slice #1, lateral margin, perpendicular (representative)
- 1C-1D: slice #4, irregular fibrous area
- 1E: slice #4, fibrous area to posterior margin
- 1F: slice #4, fibrous area to superior margin
- 1G-1H: slice #5, fibrous area contiguous section
- 1I: slice #5, posterior margin
- 1J: slice #5, inferior and posterior margins
- 1K: overlying skin
- 1L-1M: slice #6, contiguous section of fibrous area to inferior margin
- 1N-1O: posterior margin
- 1P: superior margin
- 1Q-1T: slice #7, contiguous section from superior to inferior (orange ink denotes contiguous section)
- 1U: overlying skin
- 1V: slice #8, fibrous area
- 1W: superior margin
- 1X: inferior margin
- 1Y: posterior margin
- 1Z: slice #9, inferior margin
- 1AA: slice #9, irregular fibrous area
- 1BB: superior margin
- 1CC: posterior margin
- 1DD-1GG: slice #10, medial margin, perpendicular (representative).

Specimen #2 is received in formalin labeled right axillary dissection, and consists of 11.0 x 10.0 x 2.5 cm yellow adipose tissue. The specimen was serially sectioned to reveal 16 lymph nodes ranging in size from 1.5 to 4.5 cm. The lymph nodes are entirely submitted and labeled as follows:

- 2A: Two lymph nodes intact.
- 2B: Two lymph nodes intact.
- 2C: Four lymph nodes intact.
- 2D: One lymph node, bisected.
- 2E: One lymph node, bisected.
- 2F: One lymph node, bisected.
- 2G: One lymph node, bisected.
- 2H: One lymph node, representative section.
- 2I: One lymph node, representative section.
- 2J: One lymph node, representative section.
- 2K-2L: One lymph node, representative section.

Specimen #3 is received fresh labeled omentum, and consists of a 20 x 20 x 5.0 yellow lobulated adipose tissue. The specimen is serially sectioned and no lesion is grossly identified. Representative sections are submitted labeled 3A-3B.

[page 3 of 3]
Surgical Pathology Report

Intraoperative Consult Diagnosis

1A/GDX: NEEDLE LOC WIRE ENTERS SUPERIORLY AND ONE OTHER ENTERS INFERIORLY. VAGUE AREA, NO DISCRETE MASS; MARGINS HARD TO DETERMINE; QUESTION POSTERIOR, INFERIOR, AND MEDIAL MARGIN.

*Per TSS, this is a mixed carcinoma:
lobular + pleomorphic (10-30%) type.*

BCR

END OF REPORT

Source: NCI Genomic Data Commons file 171bd1d0-d2a7-461e-af61-39c04de73aa7 (TCGA-LD-A74U.CA6A13D4-DD80-4424-B5F3-654EE31263AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).